Somatic mutation profile of tumor specimen TCGA-SQ-A6I6-01A (aliquot TCGA-SQ-A6I6-01A-11D-A35I-08) from TCGA case TCGA-SQ-A6I6, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 39.6 years (14,451 days).
Specimen TCGA-SQ-A6I6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04c70b83-ddb6-4491-861f-df40c30958eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SQ-A6I6-10A (Blood Derived Normal), aliquot TCGA-SQ-A6I6-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b475309-a874-4272-b5c2-1a8b8062da20

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2619dup p.K874* | Frame Shift Ins (INS) | VAF 65/119 reads (55%) | catalogued as rs1555614284, CI137196; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BICC1 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54061821; called by muse, mutect2
- CCNI | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs139547927; called by muse, mutect2, varscan2
- RBBP5 | c.567C>G p.F189L | Missense Mutation (SNP) | VAF 133/294 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.577); catalogued as COSV99196884; called by muse, mutect2, varscan2
- CDK5RAP3 | c.333A>C p.L111F | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM83A | c.206A>G p.Q69R | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FANCI | c.369T>A p.N123K | Missense Mutation (SNP) | VAF 126/356 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MMP27 | c.866C>A p.T289K | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH15 | c.2214C>T p.D738= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs1567778468; called by muse, mutect2, varscan2
- PPP1R13L | c.2292C>T p.Y764= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs776304474; called by muse, mutect2, varscan2
- SGSM1 | c.219C>G p.L73= | Silent (SNP) | VAF 32/39 reads (82%) | called by muse, mutect2, varscan2
